Somatic mutation profile of tumor specimen TARGET-20-PARAHF-09A (aliquot TARGET-20-PARAHF-09A-01D) from TARGET case TARGET-20-PARAHF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,472 days).
Specimen TARGET-20-PARAHF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f66fc5b3-a6b6-45b6-9cce-5634fc693f15.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARAHF-14A (Bone Marrow Normal), aliquot TARGET-20-PARAHF-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71af8a40-e0e0-4f21-8d64-716a4afe8c36

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 29/296 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2
- RUNX1 | c.1183G>A p.E395K (on ENST00000344691 / NM_001001890.3; = p.E422K on NM_001754.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV55866738, COSV55877850; called by muse, mutect2, varscan2
